MMRF case MMRF_1621 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/184e396b-4c4e-4438-9146-7d37aac0c5a4

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.2 years (22,004 days); ISS stage: I; Days to last known disease status: 1,212 days (3.3 years); Days to last follow up: 1,212 days (3.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 138 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 365 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 645 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 645 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -60 (ECOG 0): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.609 mg/dL; Immunoglobulin G 36.1 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 1.57 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.12 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 9.4 g/dL; Glucose 4.46 mmol/L; C-Reactive Protein 0.4 mg/dL.
- Day 29 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.31 ×10⁹/L; Platelets 328 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 113 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 211 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.583 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.32 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.
- Day 309 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 4.87 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.39 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.
- Day 365 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 5.14 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.73 mmol/L.
- Day 484 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.757 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 4.38 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.94 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.94 mmol/L.
- Day 563 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.877 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 4.99 g/L; Immunoglobulin A 2.25 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 673 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 764 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 7.09 g/L; Immunoglobulin A 3.28 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 848 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.74 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 932 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.857 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 7.47 g/L; Immunoglobulin A 3.8 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 1,044 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.03 mg/dL; Immunoglobulin G 8.55 g/L; Immunoglobulin A 3.45 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 1,100 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 3.49 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 1,212 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 8.56 g/L; Immunoglobulin A 3.43 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -60: Weight: 112 kg; Height: 170 cm.

Biospecimens (3 samples)
- Sample MMRF_1621_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -60 days.
- Sample MMRF_1621_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -60 days.
- Sample MMRF_1621_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 113 days.
